Somatic mutation profile of tumor specimen TCGA-HZ-A49I-01A (aliquot TCGA-HZ-A49I-01A-12D-A26I-08) from TCGA case TCGA-HZ-A49I, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 77.9 years (28,454 days).
Specimen TCGA-HZ-A49I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77ff01a3-7a7a-4fad-a544-e663e5d74ed2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HZ-A49I-10A (Blood Derived Normal), aliquot TCGA-HZ-A49I-10A-01D-A26I-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fac6f48d-5e4e-42f2-8223-d47c38417da8

The open-access MAF lists 51 somatic variants for this specimen: 39 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 11, Frame Shift Del 2, Splice Site 2, RNA 1, Nonstop Mutation 1, In Frame Del 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 46/159 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.737T>G p.M246R | Missense Mutation (SNP) | VAF 45/282 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587780074, CM157012, COSV52668375, COSV52693504, COSV52778210; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRINP2 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 52/373 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs767880163, COSV100838060, COSV100838162; called by muse, mutect2, varscan2
- CEP350 | c.7889G>A p.S2630N | Missense Mutation (SNP) | VAF 8/242 reads (3%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100854596, COSV62608412; called by muse, mutect2
- CR1L | c.680C>G p.P227R | Missense Mutation (SNP) | VAF 267/1468 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as COSV99687285; called by muse, mutect2, varscan2
- CR2 | c.2132T>A p.I711N | Missense Mutation (SNP) | VAF 18/581 reads (3%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.798); catalogued as COSV100889621; called by muse, mutect2
- CUBN | c.4351-1G>T p.X1451_splice | Splice Site (SNP) | VAF 49/287 reads (17%) | catalogued as COSV100912592; called by muse, mutect2, varscan2
- DHRS4 | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 317/2055 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100365867; called by muse, mutect2, varscan2
- FANCD2 | c.2015C>T p.P672L | Missense Mutation (SNP) | VAF 62/939 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs754258198, COSV55034828; called by muse, mutect2
- GLB1L2 | c.1838A>C p.E613A | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs769513383, COSV100335312; called by muse, mutect2, varscan2
- GPR183 | c.560T>C p.F187S | Missense Mutation (SNP) | VAF 89/515 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs576971706, COSV100854255; called by muse, mutect2, varscan2
- ITGA1 | c.3083C>T p.A1028V | Missense Mutation (SNP) | VAF 37/287 reads (13%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV99251261; called by muse, mutect2, varscan2
- KIAA1755 | c.1988G>A p.R663Q | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs763007728, COSV99641952; called by muse, mutect2, varscan2
- KIAA1755 | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as rs753912139, COSV99641812; called by muse, mutect2, varscan2
- MDM2 | c.400C>G p.H134D | Missense Mutation (SNP) | VAF 47/311 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV50706608; called by muse, mutect2, varscan2
- NIBAN3 | c.1780G>T p.A594S | Missense Mutation (SNP) | VAF 115/906 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.272); catalogued as COSV99962149, COSV99962451; called by muse, mutect2, varscan2
- NLRP2 | c.2367-2A>G p.X789_splice | Splice Site (SNP) | VAF 60/375 reads (16%) | catalogued as rs202152161, COSV54752889, COSV99672237; called by muse, mutect2, varscan2
- NR6A1 | c.172C>T p.R58* (on ENST00000487099 / NM_033334.4; = p.R54* on NM_001489.5) | Nonsense Mutation (SNP) | VAF 87/462 reads (19%) | catalogued as COSV100748534; called by muse, mutect2, varscan2
- NUDT9 | c.555T>A p.N185K | Missense Mutation (SNP) | VAF 84/292 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.091); catalogued as COSV100139213; called by muse, mutect2, varscan2
- OTUD6B | c.832_834del p.Y278del | In Frame Del (DEL) | VAF 17/87 reads (20%) | catalogued as rs746479510; called by mutect2, pindel, varscan2
- PLEC | c.12317C>T p.A4106V (on ENST00000322810 / NM_201380.4; = p.A3996V on NM_000445.5) | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs782096389, COSV100513552; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHA8 | c.883T>G p.C295G | Missense Mutation (SNP) | VAF 110/690 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99321719; called by muse, mutect2, varscan2
- PRL | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 55/255 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as rs570230762, COSV60594176; called by muse, mutect2, varscan2
- PSD | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 78/430 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs766746185, COSV50065471; called by muse, mutect2, varscan2
- RP1L1 | c.1421G>C p.R474T | Missense Mutation (SNP) | VAF 68/415 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); catalogued as rs762473621, COSV101223201; called by muse, mutect2, varscan2
- RSRC2 | c.632G>A p.R211K | Missense Mutation (SNP) | VAF 72/415 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.281); catalogued as COSV100063541; called by muse, mutect2, varscan2
- SERPINA6 | c.216G>A p.M72I | Missense Mutation (SNP) | VAF 62/323 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV100448262; called by muse, mutect2, varscan2
- SON | c.3587C>T p.P1196L | Missense Mutation (SNP) | VAF 164/982 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.139); catalogued as rs1225874870, COSV99278140; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TCF4 | c.1084T>C p.W362R | Missense Mutation (SNP) | VAF 19/704 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100610152; called by muse, mutect2
- TLL2 | c.1910C>T p.P637L | Missense Mutation (SNP) | VAF 92/652 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1366137116, COSV100780263; called by muse, mutect2, varscan2
- TTN | c.23282C>A p.P7761Q (on ENST00000591111; = p.P6834Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/93 reads (11%) | PolyPhen probably damaging (0.999); catalogued as COSV100610618; called by muse, mutect2, varscan2
- VPS13B | c.10103G>T p.G3368V | Missense Mutation (SNP) | VAF 18/670 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV100661864; called by muse, mutect2
- ZBTB17 | c.1858G>T p.G620W | Missense Mutation (SNP) | VAF 27/255 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100999011; called by muse, mutect2, varscan2
- ZC3H12A | c.617A>T p.K206M | Missense Mutation (SNP) | VAF 76/498 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201388317, COSV66104124; called by muse, varscan2
- ZNF532 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 75/376 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60174175; called by muse, mutect2, varscan2
- ARL5B | c.295_301del p.A100Qfs*28 | Frame Shift Del (DEL) | VAF 67/548 reads (12%) | called by mutect2, pindel, varscan2
- DLX5 | c.870_*1del | Nonstop Mutation (DEL) | VAF 54/386 reads (14%) | called by mutect2, pindel, varscan2
- MFHAS1 | c.866del p.P289Lfs*53 | Frame Shift Del (DEL) | VAF 50/284 reads (18%) | called by mutect2, pindel, varscan2
- ZNF611 | c.2061dup p.N688* | Frame Shift Ins (INS) | VAF 132/632 reads (21%) | called by mutect2, varscan2
- BRWD1 | c.972C>T p.G324= | Silent (SNP) | VAF 140/778 reads (18%) | catalogued as rs768846491, COSV100313343; called by muse, mutect2, varscan2
- CLEC4G | c.15G>A p.R5= | Silent (SNP) | VAF 53/330 reads (16%) | catalogued as rs778340305, COSV100183647; called by muse, mutect2, varscan2
- COL24A1 | c.2754G>A p.G918= | Silent (SNP) | VAF 79/578 reads (14%) | catalogued as COSV100993235; called by muse, mutect2, varscan2
- ENPP6 | c.873C>T p.S291= | Silent (SNP) | VAF 116/599 reads (19%) | catalogued as COSV99698749; called by muse, mutect2, varscan2
- HSPA6 | c.648T>G p.A216= | Silent (SNP) | VAF 33/273 reads (12%) | catalogued as COSV100554117, COSV59059692; called by muse, mutect2, varscan2
- LRP1B | c.10371C>T p.D3457= | Silent (SNP) | VAF 86/536 reads (16%) | catalogued as rs953684582, COSV101256233, COSV67244539; called by muse, mutect2, varscan2
- MACF1 | c.21870G>A p.P7290= (on ENST00000372915; = p.P5335= on NM_012090.5) | Silent (SNP) | VAF 108/707 reads (15%) | catalogued as rs751315719, COSV57129525; called by muse, mutect2, varscan2
- NLRC3 | c.2022G>A p.A674= | Silent (SNP) | VAF 21/138 reads (15%) | catalogued as rs748215521, COSV57087877; called by muse, mutect2, varscan2
- SEMA4A | c.426C>T p.C142= | Silent (SNP) | VAF 162/1021 reads (16%) | catalogued as rs371685429; called by muse, mutect2, varscan2
- SKAP2 | c.288C>T p.D96= | Silent (SNP) | VAF 152/1031 reads (15%) | catalogued as rs761771803, COSV100591872; called by muse, mutect2, varscan2
- SLC6A20 | c.510G>A p.P170= | Silent (SNP) | VAF 114/596 reads (19%) | catalogued as rs376095861, COSV62072074; called by muse, mutect2, varscan2
- Vault | n.5C>T | RNA (SNP) | VAF 40/265 reads (15%) | catalogued as rs368722162; called by muse, mutect2, varscan2
